Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8EK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8EK-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

-"Biopsy of the cervix":

Invasive squamous cell carcinoma histological grade 2.

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site Cervix NOS
C53.9
92

Histology acceptable - ~~DO for~~ inadequate tumor nuclei.

Tumor nuclei = 40%

will be submitted for macrodissection

Source: NCI Genomic Data Commons file 4170307d-e04f-4b00-875d-0fe6250358d9 (TCGA-VS-A8EK.C5B99AC6-E318-4608-8E70-96176F97EF90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).